Somatic mutation profile of tumor specimen C3L-02660-05 (aliquot CPT0202720006) from CPTAC case C3L-02660, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.1 years (26,351 days).
Specimen C3L-02660-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bd0fc36-1b59-43d8-b2b4-4d2caf21d362.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02660-31 (Blood Derived Normal), aliquot CPT0202840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9bc536d-1dba-49a2-87ce-2b61d774cfe0

The open-access MAF lists 368 somatic variants for this specimen: 254 protein-altering or splice-affecting, 74 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 74, Intron 17, Nonsense Mutation 15, RNA 7, Splice Site 6, 5'UTR 5, 3'UTR 5, Frame Shift Del 4, 5'Flank 3, Splice Region 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 99/611 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WNT10B | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 27/200 reads (14%) | catalogued as rs766021478; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4930C>T p.P1644S | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100933157; called by muse, mutect2, varscan2
- ADAMTS20 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1321782265, COSV101166050; called by muse, mutect2, varscan2
- ADAMTS3 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54385715; called by muse, mutect2
- ADGB | c.4470C>A p.S1490R | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs373201109; called by muse, mutect2, varscan2
- ADPRH | c.895C>A p.H299N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63696012; called by muse, mutect2, varscan2
- AFG1L | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV64555517; called by muse, mutect2
- ANKRD30A | c.3865C>A p.R1289S (on ENST00000611781; = p.R1233S on NM_052997.2) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV64624204; called by muse, mutect2
- AOX1 | c.3142G>A p.G1048R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99613657; called by muse, mutect2
- AVIL | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 91/588 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.44); catalogued as COSV57684149; called by muse, mutect2, varscan2
- BCL9 | c.3302A>C p.N1101T | Missense Mutation (SNP) | VAF 14/357 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52340759; called by muse, mutect2
- BIVM-ERCC5 | c.3706C>T p.P1236S | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265411683, COSV63245536; called by muse, mutect2, varscan2
- C1QL4 | c.49C>A p.R17S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs747239357; called by muse, mutect2
- CACNA1G | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs778361579; called by muse, mutect2
- CCDC197 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs759025132; called by muse, mutect2
- CCDC74A | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as rs529281590; called by muse, mutect2
- CDH18 | c.2283C>A p.D761E | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as rs762154267; called by muse, mutect2, varscan2
- CEP170 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs761151661; called by muse, mutect2
- CIAO2A | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV55537932; called by muse, mutect2, varscan2
- CNTN6 | c.1789C>G p.P597A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV63165467; called by muse, mutect2, varscan2
- CRAMP1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs373328340; called by muse, mutect2, varscan2
- CYRIA | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV62866614, COSV62866639; called by muse, mutect2, varscan2
- DNM1L | c.1496C>A p.P499Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56776417; called by muse, mutect2
- DPPA2 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV101524800, COSV72118350; called by muse, mutect2, varscan2
- EGFR | c.2546A>T p.Q849L | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV51825402; called by muse, mutect2
- EXOC6B | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs769294966; called by muse, mutect2, varscan2
- EXOSC1 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61749334; called by muse, mutect2
- FAM178B | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs761877797; called by muse, mutect2, varscan2
- FAM220A | c.110del p.G37Afs*11 | Frame Shift Del (DEL) | VAF 38/348 reads (11%) | catalogued as COSV57625729; called by mutect2, pindel, varscan2
- FRY | c.6763C>A p.L2255I | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.264); catalogued as COSV66577060; called by muse, mutect2, varscan2
- FUT1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs557041594, COSV59568211; called by muse, mutect2
- FUT3 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 64/681 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV54609292; called by muse, varscan2
- GRIN2D | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs888091926; called by muse, mutect2, varscan2
- GRM8 | c.2510A>T p.K837M | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100284994; called by muse, mutect2
- HIPK1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65786373; called by muse, mutect2
- KCNT2 | c.1640C>A p.T547K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs774233172, COSV54098387; called by muse, mutect2, varscan2
- KIAA1755 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1399872179; called by muse, mutect2
- KLHL15 | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV60140441; called by muse, mutect2
- LCE3D | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs141162662; called by muse, mutect2, varscan2
- LGMN | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1803450; called by muse, mutect2, varscan2
- LOXL3 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs773238218; called by muse, mutect2, varscan2
- LRFN5 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99982009; called by muse, mutect2
- LRP1 | c.11843G>A p.G3948D | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs755874188; called by muse, mutect2, varscan2
- MGAM2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.036); catalogued as rs774022413, COSV72176806; called by muse, mutect2
- NAV3 | c.3347G>A p.G1116D | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99031105, COSV99896012; called by muse, mutect2
- NUDT7 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51746006; called by muse, mutect2
- NUTM1 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61545821; called by muse, mutect2
- OR10R2 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774529513; called by muse, mutect2, varscan2
- OR10W1 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs140685832, COSV67720500; called by muse, mutect2, varscan2
- OR10Z1 | c.651del p.Y218Tfs*9 | Frame Shift Del (DEL) | VAF 39/324 reads (12%) | catalogued as COSV100778915, COSV63524906; called by mutect2, pindel, varscan2
- OR13J1 | c.647T>A p.L216Q | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746253034; called by muse, mutect2, varscan2
- OR2T35 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1009534401; called by muse, mutect2, varscan2
- OR8G5 | c.475C>G p.H159D | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV58383282; called by muse, mutect2, varscan2
- OSBPL8 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53881283; called by muse, mutect2
- PGPEP1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 185/566 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.102); catalogued as rs373180895; called by muse, mutect2, varscan2
- PPFIA4 | c.3434C>T p.P1145L (on ENST00000447715; = p.P1146L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429089497, COSV99690945; called by muse, mutect2
- PTPN18 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs371739121, COSV51559036; called by muse, mutect2, varscan2
- SACS | c.11375G>A p.R3792Q | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as rs778633704; called by muse, mutect2, varscan2
- SI | c.3544G>T p.A1182S | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as COSV52282820; called by muse, mutect2, varscan2
- SNRNP200 | c.5527C>T p.R1843* | Nonsense Mutation (SNP) | VAF 58/474 reads (12%) | catalogued as COSV55531968; called by muse, mutect2, varscan2
- SPATA32 | c.67C>A p.R23= | Splice Region (SNP) | VAF 16/244 reads (7%) | catalogued as COSV59302925; called by muse, mutect2
- SYCP2 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.173); catalogued as COSV100698061; called by muse, mutect2
- TBC1D21 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV100311336; called by muse, mutect2
- THSD7A | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs543568226, COSV70261873; called by muse, mutect2, varscan2
- TRIOBP | c.6533G>A p.R2178Q (on ENST00000644935 / NM_001039141.3; = p.R465Q on NM_007032.5) | Missense Mutation (SNP) | VAF 33/527 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs1217762243; called by muse, mutect2
- UBQLNL | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV100974514; called by muse, mutect2, varscan2
- UNC13A | c.3022T>A p.Y1008N | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53204042; called by muse, mutect2
- VEGFA | c.115G>T p.E39* (on ENST00000523873 / NM_001171623.1; = p.E219* on NM_003376.6) | Nonsense Mutation (SNP) | VAF 36/418 reads (9%) | catalogued as COSV57877687; called by muse, mutect2
- ZBED9 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.264); catalogued as rs1329299227; called by muse, mutect2, varscan2
- ZNF479 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as COSV58639065; called by muse, mutect2
- ZNF567 | c.473G>T p.R158I (on ENST00000536254 / NM_001322913.1; = p.R127I on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as COSV62446511; called by muse, mutect2
- ZNF99 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as COSV68055673; called by muse, mutect2
- AC098582.1 | c.155A>C p.D52A | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.308); called by muse, varscan2
- AC103993.1 | n.127T>A | Splice Region (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- ACSM1 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ACSM5 | c.825G>T p.W275C | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM9 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS16 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- AFM | c.364A>G p.R122G | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- AHNAK | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- AHNAK | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AK9 | c.2513T>C p.F838S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2
- AMY1B | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ANKRD36B | c.1471A>T p.R491W | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2
- APOB | c.7875G>T p.R2625S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ARHGAP15 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP6 | c.2720C>T p.P907L (on ENST00000337414 / NM_013427.3; = p.P704L on NM_013423.3) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARID1A | c.2883G>T p.M961I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ASB10 | c.746G>T p.W249L (on ENST00000420175 / NM_001142459.2; = p.W234L on NM_080871.4) | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- BHLHA15 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 88/900 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BID | c.81G>T p.L27= | Splice Region (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- C11orf24 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- C16orf78 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- CACNG3 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- CCDC146 | c.1504A>C p.K502Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCSAP | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CDK14 | c.873A>C p.E291D (on ENST00000380050 / NM_001287135.2; = p.E273D on NM_012395.3) | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- CDSN | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 44/707 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHI3L2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CHST14 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 53/544 reads (10%) | called by muse, mutect2
- CLIP2 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COA5 | c.99+2T>A p.X33_splice | Splice Site (SNP) | VAF 101/607 reads (17%) | called by muse, mutect2, varscan2
- COL2A1 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.583); called by muse, mutect2
- COQ9 | c.43T>A p.W15R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPAMD8 | c.787A>G p.N263D (on ENST00000651564; = p.N216D on NM_015692.5) | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRLF1 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- CRTAP | c.1116T>A p.Y372* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- CXCL6 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CYBB | c.655del p.A220Pfs*22 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CYP11B2 | c.739T>A p.W247R | Missense Mutation (SNP) | VAF 98/785 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DLC1 | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2
- DNAH5 | c.8768G>T p.G2923V | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DNAH7 | c.3586C>T p.Q1196* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- DNASE2 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2
- DSEL | c.2902A>G p.K968E | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2153T>A p.M718K | Missense Mutation (SNP) | VAF 23/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- ENAM | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 19/285 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); called by muse, mutect2
- EPHA6 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ERCC6L2 | c.1814G>T p.W605L | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EVC2 | c.2175G>T p.Q725H | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.647); called by muse, mutect2
- EVC2 | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FAM184B | c.2398G>C p.G800R | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- FAM83H | c.2654G>T p.G885V | Missense Mutation (SNP) | VAF 70/998 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.396); called by muse, mutect2
- FRAT1 | c.698A>T p.Q233L | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2
- FREM1 | c.5932C>T p.Q1978* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- FREM2 | c.9394G>T p.V3132L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); called by muse, mutect2
- FRMD5 | c.28A>T p.S10C | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FSHR | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GLB1L3 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GOLGA5 | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- H4C8 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- HAUS6 | c.1750A>T p.T584S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- HEPH | c.265G>T p.E89* (on ENST00000343002; = p.E143* on NM_138737.5) | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- HEPH | c.2122G>T p.G708W (on ENST00000343002; = p.G441W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHIPL2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HHLA1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- HHLA1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLCS | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- HSD17B11 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- HSP90AA1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.185); called by muse, mutect2
- IFIH1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2
- IFTAP | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGFBP5 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IGHM | c.1319A>T p.D440V | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- IGHV3-23 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IKZF1 | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- IMMP2L | c.467G>T p.W156L | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- INTS1 | c.6527A>T p.Q2176L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH8 | c.1642C>A p.Q548K | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2
- KCNQ5 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549 | c.3679G>A p.V1227M | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KIF16B | c.3448-1G>T p.X1150_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- KIF16B | c.3398T>G p.L1133W | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- KIFAP3 | c.1226A>G p.H409R | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2
- KIR3DL1 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 61/776 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.974); called by muse, mutect2
- KLHL3 | c.281A>T p.K94M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- KPNA3 | c.770A>T p.N257I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- KRT34 | c.1296G>T p.K432N | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.048); called by muse, mutect2
- LIME1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP12 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- LRRC75A | c.640C>A p.L214I (on ENST00000470794 / NM_001113567.3; = p.P175H on NM_207387.4) | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRN4CL | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- LYAR | c.1024A>T p.T342S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAPK15 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MED23 | c.2858C>A p.P953H | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MIOS | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- MKRN3 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRC1 | c.3535T>A p.W1179R | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTX1 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2
- MYCBPAP | c.1854G>C p.K618N | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- MYO1B | c.1162A>G p.I388V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, varscan2
- NAIF1 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NAP1L3 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV3 | c.1610T>A p.V537E | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCOR2 | c.3381+1G>T p.X1127_splice | Splice Site (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2
- NCOR2 | c.2285C>A p.T762K | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- NOTCH1 | c.2920G>C p.G974R | Missense Mutation (SNP) | VAF 79/554 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH2 | c.3124G>C p.D1042H | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH3 | c.4192G>T p.D1398Y | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NSD1 | c.3193G>T p.D1065Y | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2
- ODF2L | c.1406G>C p.C469S (on ENST00000317336; = p.C440S on NM_020729.3) | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2G6 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ORC5 | c.233A>T p.N78I | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- OTOP2 | c.1597T>C p.W533R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC4L | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2
- PCYT2 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.155); called by muse, mutect2
- PDE4A | c.1864G>T p.E622* (on ENST00000380702 / NM_001111307.2; = p.E383* on NM_006202.3) | Nonsense Mutation (SNP) | VAF 59/360 reads (16%) | called by muse, mutect2, varscan2
- PEG3 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- PEX11B | c.313del p.A105Lfs*29 | Frame Shift Del (DEL) | VAF 37/257 reads (14%) | called by mutect2, pindel, varscan2
- PF4 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- PGLYRP2 | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- PKD1L2 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- PKHD1 | c.1765C>A p.R589S | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PPP1R12A | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); called by muse, mutect2
- PPT2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 9/281 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- PRMT6 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PYHIN1 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- RANBP17 | c.2637+1G>C p.X879_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- RHCG | c.758C>G p.T253S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2
- RIMS1 | c.4776G>T p.K1592N | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RING1 | c.1155T>A p.N385K | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2
- RIPPLY2 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- RPL10L | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- RUFY4 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SEL1L2 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2
- SLAIN1 | c.683G>T p.C228F (on ENST00000466548; = p.C86F on NM_001040153.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SLAIN1 | c.1015C>T p.L339F (on ENST00000466548; = p.L76F on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SLC5A1 | c.865T>A p.W289R | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- SLC6A11 | c.1810C>A p.P604T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX17 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 30/404 reads (7%) | called by muse, mutect2
- SPHKAP | c.1448T>A p.L483H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SPINT2 | c.105C>A p.H35Q | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- SPINT2 | c.107-2A>T p.X36_splice | Splice Site (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- SPRED3 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- STK36 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- STK38L | c.1180A>G p.R394G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2
- STX8 | c.118-1G>T p.X40_splice | Splice Site (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- SYNE1 | c.21392A>G p.Q7131R (on ENST00000367255 / NM_182961.4; = p.Q7060R on NM_033071.3) | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SYNRG | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TAF4 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TECPR1 | c.3105G>T p.R1035S | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- TENT4B | c.1094G>T p.R365M (on ENST00000561678 / NM_001365323.2; = p.R350M on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEP1 | c.7015G>T p.D2339Y | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2
- TGFB1 | c.833G>C p.R278P | Missense Mutation (SNP) | VAF 114/464 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TGM6 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TIAM2 | c.2075T>G p.F692C | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TICRR | c.873T>G p.N291K | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TKTL1 | c.690_694dup p.H232Lfs*18 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- TMCO6 | c.1288C>T p.H430Y | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2
- TMEM132D | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TMEM8B | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TNRC6A | c.1828A>G p.T610A | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TPH2 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2
- TRHR | c.840G>T p.M280I | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- TRIM27 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- TRIM56 | c.1742G>T p.W581L | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); called by muse, mutect2
- TRIM56 | c.1743G>T p.W581C | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- TTC28 | c.1280T>A p.L427* | Nonsense Mutation (SNP) | VAF 33/322 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.35606A>T p.E11869V (on ENST00000591111; = p.E4445V on NM_003319.4) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | PolyPhen benign (0.021); called by muse, mutect2
- TTN | c.14699G>T p.S4900I (on ENST00000591111; = p.S3973I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/113 reads (8%) | PolyPhen benign (0.325); called by muse, mutect2
- USP17L7 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 36/810 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP30 | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- WDR81 | c.3248A>G p.E1083G (on ENST00000409644 / NM_001163809.2; = p.E32G on NM_152348.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2
- WNT7A | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- ZBED9 | c.3707T>A p.L1236* | Nonsense Mutation (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- ZDHHC19 | c.337T>C p.W113R | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX4 | c.3251A>T p.Q1084L | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZFPM2 | c.2657A>T p.D886V | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.095); called by muse, mutect2
- ZNF226 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF300 | c.1345A>T p.K449* | Nonsense Mutation (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- ZNF554 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF560 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.053); called by muse, mutect2
- ZNF786 | c.808A>T p.N270Y | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2
- ABCA13 | c.3519A>T p.T1173= | Silent (SNP) | VAF 32/193 reads (17%) | called by muse, mutect2, varscan2
- ABCC12 | c.3852C>G p.T1284= | Silent (SNP) | VAF 22/239 reads (9%) | called by muse, mutect2
- ADAMTS16 | c.480C>T p.A160= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99941731; called by muse, varscan2
- ADAMTSL4 | c.489C>T p.P163= | Silent (SNP) | VAF 53/522 reads (10%) | called by muse, mutect2, varscan2
- BCL11B | c.2577C>T p.C859= (on ENST00000357195 / NM_001282237.2; = p.C788= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/604 reads (5%) | catalogued as rs1209943325; called by muse, mutect2
- BEND3 | c.741G>A p.Q247= | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- BHMT | c.138T>C p.P46= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- C2CD2L | c.1653G>A p.A551= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as rs1182097793, COSV60884766; called by muse, mutect2, varscan2
- CDH7 | c.324G>A p.K108= | Silent (SNP) | VAF 51/341 reads (15%) | catalogued as COSV100543189; called by muse, mutect2, varscan2
- DOK1 | c.228C>G p.V76= | Silent (SNP) | VAF 62/446 reads (14%) | called by muse, mutect2, varscan2
- DPYS | c.81G>T p.V27= | Silent (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2, varscan2
- EBF4 | c.1473G>A p.V491= (on ENST00000609451; = p.V487= on NM_001110514.1) | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- EEF1D | c.135G>C p.V45= | Silent (SNP) | VAF 16/235 reads (7%) | called by muse, mutect2
- EIF2D | c.1488A>C p.A496= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- ERN1 | c.735C>T p.V245= | Silent (SNP) | VAF 65/503 reads (13%) | catalogued as rs575026496; called by muse, mutect2, varscan2
- FBXO40 | c.570G>A p.G190= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- FTHL17 | c.525C>T p.T175= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100784380, COSV63267899; called by muse, varscan2
- GFPT2 | c.1113C>T p.I371= | Silent (SNP) | VAF 21/208 reads (10%) | called by muse, mutect2
- GGTLC1 | c.372G>A p.V124= | Silent (SNP) | VAF 84/942 reads (9%) | catalogued as rs576331951; called by muse, mutect2
- GPATCH4 | c.336G>A p.Q112= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs376280034; called by muse, mutect2, varscan2
- GPR32 | c.951C>A p.V317= | Silent (SNP) | VAF 28/264 reads (11%) | called by muse, mutect2, varscan2
- HDC | c.435C>T p.V145= | Silent (SNP) | VAF 38/322 reads (12%) | called by muse, mutect2, varscan2
- HHLA1 | c.195G>T p.T65= | Silent (SNP) | VAF 15/312 reads (5%) | catalogued as COSV70153820; called by muse, mutect2
- IRF4 | c.960C>A p.A320= | Silent (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- KCNH4 | c.1740C>T p.G580= | Silent (SNP) | VAF 44/440 reads (10%) | catalogued as COSV99237555; called by muse, mutect2, varscan2
- KNOP1 | c.387G>A p.V129= | Silent (SNP) | VAF 33/235 reads (14%) | catalogued as rs1355225309; called by muse, mutect2, varscan2
- LAMA2 | c.2286T>C p.H762= | Silent (SNP) | VAF 46/299 reads (15%) | catalogued as rs762354749; called by muse, mutect2, varscan2
- LARGE2 | c.2106G>C p.G702= | Silent (SNP) | VAF 40/436 reads (9%) | called by muse, mutect2
- LRP8 | c.2721T>A p.L907= | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- LRRN4 | c.1986A>C p.P662= | Silent (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- MEIOC | c.96G>A p.A32= | Silent (SNP) | VAF 38/203 reads (19%) | catalogued as COSV63439642; called by muse, mutect2, varscan2
- MOGAT3 | c.366C>A p.G122= | Silent (SNP) | VAF 54/578 reads (9%) | called by muse, mutect2
- MTTP | c.1980C>T p.H660= | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as rs369526713; called by muse, mutect2, varscan2
- MYO15A | c.2424G>T p.P808= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- NAIF1 | c.606G>T p.V202= | Silent (SNP) | VAF 38/347 reads (11%) | called by muse, mutect2, varscan2
- NANOG | c.252C>G p.V84= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV57552036; called by muse, mutect2, varscan2
- NKX1-2 | c.399C>T p.D133= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV101465359; called by muse, mutect2
- OR2M7 | c.414C>A p.P138= | Silent (SNP) | VAF 36/246 reads (15%) | catalogued as rs1426996056; called by muse, mutect2, varscan2
- OR2T4 | c.939C>T p.L313= | Silent (SNP) | VAF 63/475 reads (13%) | called by muse, mutect2, varscan2
- OR5W2 | c.606C>A p.V202= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs780345080, COSV100747530, COSV60616093; called by muse, mutect2
- OTUD6A | c.765C>A p.I255= | Silent (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- PAX8 | c.951T>G p.S317= | Silent (SNP) | VAF 24/168 reads (14%) | called by muse, varscan2
- PCDHA8 | c.1758C>G p.G586= | Silent (SNP) | VAF 42/526 reads (8%) | called by muse, mutect2
- PCDHGA4 | c.744A>T p.G248= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- PCDHGB1 | c.1791C>T p.N597= | Silent (SNP) | VAF 30/380 reads (8%) | catalogued as rs1319194846, COSV54051120; called by muse, mutect2
- PDCD1 | c.738G>T p.T246= | Silent (SNP) | VAF 30/197 reads (15%) | catalogued as COSV100545408, COSV100545477; called by muse, mutect2, varscan2
- PDS5A | c.1212G>A p.R404= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- POU4F3 | c.186G>T p.A62= | Silent (SNP) | VAF 28/357 reads (8%) | catalogued as COSV57944103; called by muse, mutect2
- PTPRB | c.5076C>T p.F1692= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV54235088; called by muse, mutect2
- RELCH | c.303G>T p.L101= | Silent (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- RHO | c.33G>T p.V11= | Silent (SNP) | VAF 22/250 reads (9%) | catalogued as COSV56212537; called by muse, mutect2
- RNF148 | c.627C>T p.C209= | Silent (SNP) | VAF 25/221 reads (11%) | catalogued as rs753838190; called by muse, mutect2, varscan2
- RYR1 | c.3021C>T p.S1007= | Silent (SNP) | VAF 169/693 reads (24%) | catalogued as rs143891703; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCN10A | c.3447G>T p.V1149= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.900C>T p.C300= | Silent (SNP) | VAF 18/239 reads (8%) | catalogued as rs759776062, COSV63530612; called by muse, mutect2
- SH2D4B | c.850C>T p.L284= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs1564780995; called by muse, mutect2
- SLC2A12 | c.204C>T p.I68= | Silent (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- SLC5A3 | c.1269A>T p.I423= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- SLC7A14 | c.174C>T p.L58= | Silent (SNP) | VAF 78/673 reads (12%) | catalogued as COSV99200574; called by muse, mutect2, varscan2
- SRCIN1 | c.1023G>T p.S341= (on ENST00000621492; = p.S307= on NM_025248.3) | Silent (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- STYXL2 | c.798C>A p.G266= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs202090160; called by muse, mutect2, varscan2
- TEK | c.2280G>T p.L760= | Silent (SNP) | VAF 16/333 reads (5%) | catalogued as COSV66235343; called by muse, mutect2
- TGM6 | c.963G>A p.L321= | Silent (SNP) | VAF 44/293 reads (15%) | called by muse, mutect2, varscan2
- THSD7A | c.831C>T p.R277= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs377308966, COSV70261643; called by muse, mutect2, varscan2
- TIAM2 | c.2076C>T p.F692= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as rs561505204; called by muse, mutect2
- TJP1 | c.1830C>A p.S610= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- TMEM74 | c.522A>T p.I174= | Silent (SNP) | VAF 25/220 reads (11%) | called by muse, mutect2, varscan2
- TRIO | c.7686C>T p.Y2562= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- TTN | c.50520C>T p.G16840= (on ENST00000591111; = p.G9416= on NM_003319.4) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs878963234; called by muse, mutect2, varscan2
- UNC93A | c.786G>A p.L262= | Silent (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- VWA5B2 | c.2697G>A p.E899= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- ZFHX4 | c.5850A>T p.T1950= | Silent (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- ZNF616 | c.444G>T p.L148= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.1443A>G p.P481= | Silent (SNP) | VAF 38/382 reads (10%) | called by muse, mutect2, varscan2
- ABCA7 | c.498+81A>C | Intron (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659413 G>A | 5'Flank (SNP) | VAF 8/104 reads (8%) | catalogued as rs1161985661; called by muse, mutect2
- AC092656.1 | n.215C>A | RNA (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- AC244258.1 | n.965G>T | RNA (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- AL161729.4 | chr9:95516755 G>T | 3'Flank (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- ANKRD12 | c.943+13679A>T | Intron (SNP) | VAF 53/188 reads (28%) | called by muse, mutect2, varscan2
- ASB8 | c.235-123G>C | Intron (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- C5orf38 | c.*188G>A | 3'UTR (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- CACNA1E | c.5268-1964A>C | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CD200 | c.*19T>G | 3'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- CR1 | c.487+15228G>T | Intron (SNP) | VAF 29/346 reads (8%) | catalogued as COSV100887936; called by muse, mutect2
- CYP2A7P1 | n.152G>T | RNA (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- DAPK2 | c.858+1781G>T | Intron (SNP) | VAF 85/590 reads (14%) | called by muse, mutect2, varscan2
- DNM1 | c.1336-20G>C | Intron (SNP) | VAF 22/237 reads (9%) | called by muse, mutect2
- EPSTI1 | chr13:42888385 T>A | 3'Flank (SNP) | VAF 19/264 reads (7%) | called by muse, mutect2
- ERVV-1 | chr19:53010543 C>G | 5'Flank (SNP) | VAF 75/294 reads (26%) | called by muse, mutect2, varscan2
- GNB5 | c.494+69C>T | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- GP2 | chr16:20327587 G>A | 5'Flank (SNP) | VAF 39/320 reads (12%) | called by muse, mutect2, varscan2
- GPR132 | c.34+1287C>A | Intron (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- GREB1L | c.2182+21A>G | Intron (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- HMG20B | c.941+101A>T | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- HOXD10 | c.-30C>T | 5'UTR (SNP) | VAF 18/120 reads (15%) | catalogued as rs1423561800; called by muse, mutect2, varscan2
- ICOS | c.-37C>A | 5'UTR (SNP) | VAF 43/198 reads (22%) | called by muse, mutect2, varscan2
- IDI1 | chr10:1036811 G>A | 3'Flank (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- LINC02145 | n.284A>T | RNA (SNP) | VAF 42/280 reads (15%) | called by muse, mutect2, varscan2
- OPA1 | c.1936-15A>G | Intron (SNP) | VAF 8/71 reads (11%) | catalogued as rs547740597; called by muse, mutect2, varscan2
- PLA2G1B | c.-17C>T | 5'UTR (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- PPP4R1L | n.1790A>T | RNA (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- RPL28 | c.*3390_*3396del | 3'UTR (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- RPN2 | c.1883+1738A>G | Intron (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.559-11T>A | Intron (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2
- SCN7A | c.2158-3628A>C | Intron (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2
- SRP68 | c.*376G>A | 3'UTR (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2
- TMC7 | c.-61G>T | 5'UTR (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- TSPO | c.*12A>T | 3'UTR (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- UBA52 | c.-2A>G | 5'UTR (SNP) | VAF 33/271 reads (12%) | called by muse, mutect2, varscan2
- UBE2DNL | n.303T>A | RNA (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- WNK4 | c.792-35C>A | Intron (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- XKR6 | c.764+137778G>C | Intron (SNP) | VAF 13/251 reads (5%) | called by muse, mutect2
- ZNF849P | n.1287A>G | RNA (SNP) | VAF 61/229 reads (27%) | called by muse, mutect2, varscan2
